Somatic mutation profile of tumor specimen TCGA-LN-A9FP-01A (aliquot TCGA-LN-A9FP-01A-31D-A387-09) from TCGA case TCGA-LN-A9FP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,104 days).
Specimen TCGA-LN-A9FP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e3f13c2-b778-44f2-9db1-d8d6aedae552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A9FP-10A (Blood Derived Normal), aliquot TCGA-LN-A9FP-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03707e4f-5879-4c13-bde7-6a9bb24dfb7d

The open-access MAF lists 371 somatic variants for this specimen: 275 protein-altering or splice-affecting, 84 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 237, Silent 84, Nonsense Mutation 24, Splice Site 9, RNA 4, Intron 3, 5'Flank 3, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2
- ACE | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV52007047; called by muse, mutect2, varscan2
- ADAMTSL3 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272213423; called by muse, mutect2
- ADH7 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs148026590; called by muse, mutect2, varscan2
- AKAP3 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs140759485; called by muse, mutect2, varscan2
- ALDOB | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV66398647; called by muse, mutect2, varscan2
- APOB | c.8939C>G p.S2980C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV51941418; called by muse, mutect2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, mutect2
- ASIC1 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.093); catalogued as COSV99948202; called by mutect2, varscan2
- ASIC2 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as COSV100726063, COSV100726672; called by muse, mutect2, varscan2
- ASPSCR1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV60731294; called by muse, mutect2
- ATP13A5 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.852); catalogued as COSV60865508; called by muse, mutect2, varscan2
- ATP2A3 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59236227; called by muse, mutect2
- ATP2B4 | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58185985; called by mutect2, varscan2
- BANP | c.815G>T p.G272V (on ENST00000286122; = p.G241V on NM_017869.4) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53742217; called by muse, mutect2
- BBS7 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CM1310187, COSV52659000; called by muse, mutect2, varscan2
- C14orf28 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as rs771127672, COSV57333040; called by muse, mutect2, varscan2
- CACNA1A | c.2435C>A p.T812K | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs748099275, COSV64208189; called by muse, mutect2
- CCDC7 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.998); catalogued as COSV53234038; called by muse, mutect2, varscan2
- CCER1 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62647190; called by muse, mutect2, varscan2
- CDH22 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64838389; called by muse, mutect2, varscan2
- CELF3 | c.846C>G p.Y282* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV51886149; called by muse, mutect2, varscan2
- CFAP36 | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 4/67 reads (6%) | catalogued as rs989408506; called by muse, mutect2
- CFTR | c.2537G>T p.W846L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as CM930121; called by muse, mutect2, varscan2
- CIT | c.5771G>T p.R1924L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99949595; called by muse, mutect2, varscan2
- CRB1 | c.849-1G>T p.X283_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100959172, COSV66347542; called by muse, mutect2, varscan2
- CSMD3 | c.332C>G p.A111G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV52342262; called by muse, mutect2, varscan2
- CTTNBP2NL | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201675639; called by muse, mutect2, varscan2
- DHX8 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.321); catalogued as COSV52253542; called by muse, mutect2, varscan2
- DSCAML1 | c.1069A>T p.T357S (on ENST00000321322; = p.T297S on NM_020693.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.182); catalogued as COSV58383820; called by muse, mutect2, varscan2
- EIF4A3 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53920665; called by muse, mutect2, varscan2
- ENAM | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV101252887, COSV68536735; called by muse, mutect2, varscan2
- FADS3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV53877717; called by muse, mutect2, varscan2
- FBN3 | c.4582G>C p.G1528R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54465588; called by muse, mutect2, varscan2
- FLG | c.6343C>T p.Q2115* | Nonsense Mutation (SNP) | VAF 18/344 reads (5%) | catalogued as COSV64237943; called by muse, mutect2
- GNA15 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99505494; called by muse, mutect2
- GPRC5B | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56027696; called by muse, mutect2, varscan2
- GRINA | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.305); catalogued as rs1554750682; called by muse, mutect2, varscan2
- H2AC20 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs1553759933, COSV58611674, COSV58612207; called by muse, mutect2
- H2AZ2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as rs926465930, COSV99760384; called by muse, mutect2
- HDAC4 | c.2686G>T p.G896C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61874794; called by muse, mutect2, varscan2
- HDLBP | c.1617G>A p.E539= | Splice Region (SNP) | VAF 7/114 reads (6%) | catalogued as rs1192200802; called by muse, mutect2
- HDLBP | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs757592730; called by muse, mutect2, varscan2
- HKDC1 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100664788; called by mutect2, varscan2
- HYDIN | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99862296; called by muse, mutect2, varscan2
- IGLV3-19 | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs567862059; called by muse, mutect2
- ITGA2B | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs956147023; called by muse, mutect2, varscan2
- KANSL1 | c.1652+1G>T p.X551_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | catalogued as CS124331, COSV52267422, COSV52272538; called by muse, mutect2, varscan2
- LRRFIP1 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833906, COSV57834818; called by muse, mutect2
- LTBP1 | c.4066G>C p.A1356P (on ENST00000404816 / NM_206943.4; = p.A1030P on NM_000627.4) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as COSV55383165; called by muse, mutect2, varscan2
- MAGI2 | c.2866C>A p.R956S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62677423; called by muse, mutect2, varscan2
- MCOLN1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99900717; called by muse, mutect2
- MPP5 | c.1922C>A p.T641K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.339); catalogued as COSV55528297, COSV55528976; called by muse, mutect2
- MROH6 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs781456662; called by muse, mutect2, varscan2
- MROH7 | c.2292G>T p.Q764H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV100272714; called by muse, mutect2
- MYL6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV52878977; called by muse, mutect2
- OFD1 | c.2288C>A p.P763H | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV60794818; called by muse, mutect2
- OGDHL | c.1539G>T p.M513I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65104918; called by muse, mutect2, varscan2
- OR2T33 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58815358; called by muse, mutect2
- OR2T4 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63544899; called by muse, mutect2, varscan2
- PCDHA12 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56480564; called by muse, mutect2
- PCNX3 | c.5296C>T p.R1766C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63135518; called by muse, mutect2, varscan2
- PHACTR1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100279327, COSV60682441; called by muse, mutect2, varscan2
- PLB1 | c.2326G>T p.G776* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as rs1246142335; called by muse, mutect2, varscan2
- PLG | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99804235; called by muse, mutect2, varscan2
- PPFIA2 | c.1355G>T p.R452M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs756345122; called by muse, mutect2
- PPP2R5C | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV100159509; called by muse, mutect2, varscan2
- PRKCI | c.450G>T p.R150S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV99855781; called by muse, mutect2, varscan2
- RANBP3 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.949); catalogued as COSV50387090; called by muse, mutect2, varscan2
- RELN | c.1858C>A p.H620N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as rs1483467031; called by muse, mutect2, varscan2
- SAGE1 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV100187716; called by muse, mutect2
- SAMD7 | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV59422121; called by muse, mutect2, varscan2
- SAMD9 | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1333144904; called by muse, mutect2
- SCN1A | c.5911G>T p.E1971* (on ENST00000303395 / NM_001202435.3; = p.E1960* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as rs1553519738; called by muse, mutect2, varscan2
- SLC44A5 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63759224; called by muse, mutect2
- SPATA31D1 | c.4628C>A p.P1543Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV61200157; called by muse, mutect2, varscan2
- STOML3 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV65510963; called by muse, mutect2, varscan2
- SVEP1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs748669116; called by muse, mutect2, varscan2
- TAB1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs745450445, COSV99044998; called by muse, mutect2, varscan2
- TARS3 | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482021569; called by muse, mutect2
- TCP1 | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs927505050; called by muse, mutect2, varscan2
- TDP2 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV57764083; called by muse, mutect2
- TG | c.7021G>C p.G2341R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55094384; called by muse, mutect2, varscan2
- THSD1 | c.2462A>T p.E821V | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51626748; called by muse, mutect2
- TRHDE | c.1337G>T p.W446L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53857316; called by muse, mutect2
- TRIM3 | c.1067G>C p.R356P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV61985668; called by muse, mutect2, varscan2
- TRPC4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100156313, COSV59014226; called by mutect2, varscan2
- TTLL9 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV60598084; called by muse, mutect2, varscan2
- UAP1L1 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV100814487; called by muse, mutect2, varscan2
- UBE2O | c.2299G>T p.V767L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777756089; called by mutect2, varscan2
- USH2A | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56373150; called by muse, mutect2, varscan2
- VSX2 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV56216591; called by muse, mutect2, varscan2
- XPO6 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58970063; called by muse, mutect2, varscan2
- ZC3H13 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV54460655; called by muse, mutect2, varscan2
- ZNF750 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV53960248; called by muse, mutect2, varscan2
- AC011455.2 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ACVRL1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ADCY10 | c.4149G>T p.L1383F | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- AIMP1 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- AKR1A1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKR1C4 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ALKBH1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRA2 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ANKRD27 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD49 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ARHGEF15 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARRB2 | c.55-1G>C p.X19_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2
- ASCC1 | c.752G>T p.G251V (on ENST00000342444 / NM_001369085.1; = p.G223V on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL2 | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- ATAD1 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- ATF7IP | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ATP10D | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- ATP2B1 | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATXN2 | c.922G>C p.A308P (on ENST00000550104; = p.A148P on NM_002973.4) | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BABAM1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- BAIAP2 | c.1336A>T p.S446C | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); called by muse, mutect2
- BEGAIN | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C12orf66 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2
- C6orf136 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); called by muse, mutect2
- CABP5 | c.367G>C p.G123R | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAGE1 | c.1556dup p.L519Ffs*6 (on ENST00000512086; = p.L383Ffs*6 on NM_205864.3) | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- CALML5 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CCDC144A | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- CCDC15 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- CCL18 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- CCNT2 | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCNY | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDCA8 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CENPF | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- CEP250 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CINP | c.469A>T p.R157W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- CLIP2 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- COL12A1 | c.5592G>A p.W1864* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- COL22A1 | c.1528C>G p.P510A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CPAMD8 | c.1804C>A p.P602T (on ENST00000651564; = p.P555T on NM_015692.5) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CREBBP | c.7019G>A p.S2340N | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.035); called by muse, mutect2
- CRTC3 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2
- CTAGE1 | c.349T>A p.C117S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- CTSL | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DCAF12L2 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DGAT2L6 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- DGKB | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DIO3 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DLG4 | c.1685G>T p.C562F (on ENST00000399506 / NM_001321075.3; = p.C605F on NM_001365.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- DRAXIN | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DRAXIN | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DUXA | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- E2F6 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- EIPR1 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ELAPOR2 | c.1428G>T p.Q476H (on ENST00000450689 / NM_001142749.3; = p.Q309H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ELF1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2
- ELN | c.1415-2A>T p.X472_splice | Splice Site (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- ELOVL5 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERICH1 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- EYS | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- FADS1 | c.1296C>A p.F432L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM234B | c.1835G>C p.R612T | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCGBP | c.6688G>T p.A2230S | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.31); called by muse, mutect2
- FLG2 | c.3315C>A p.H1105Q | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FREM2 | c.6541C>A p.P2181T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FRMD3 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAS2L2 | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- GNLY | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GP6 | c.1006G>T p.G336W | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRAMD1C | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- GTF2IRD1 | c.577A>T p.S193C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HSD3B2 | c.711G>T p.R237S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- HYKK | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- IFT81 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- IGHV3-53 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- IGKV1D-8 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- IGKV4-1 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ITGA10 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ITGA3 | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- KBTBD6 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIR2DS4 | c.78C>A p.H26Q | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.141); called by muse, mutect2
- KPNA2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRBA1 | c.1583G>C p.G528A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT33B | c.1000C>G p.R334G | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- KRT6C | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2
- LAIR1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAMB4 | c.4212G>C p.R1404S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- LARP7 | c.998-1G>C p.X333_splice | Splice Site (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- LCA5L | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LCE2C | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LENG8 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- LRP1B | c.10885G>T p.V3629L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.132); called by muse, mutect2
- MACF1 | c.11647G>A p.E3883K (on ENST00000372915; = p.E1816K on NM_012090.5) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- MAP6 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEGF6 | c.2102G>T p.C701F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL18 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.251); called by muse, mutect2
- MUC15 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.154); called by muse, mutect2
- MUC4 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- MUC5B | c.5396C>A p.P1799Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC7 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MYCBPAP | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYH13 | c.5758C>A p.Q1920K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- MYH14 | c.2845G>A p.G949S | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- NEDD8 | c.176A>T p.Y59F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2
- NFKB1 | c.1513G>A p.A505T (on ENST00000394820 / NM_001382627.1; = p.A506T on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NKAIN4 | c.367G>C p.G123R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOMO2 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NWD1 | c.2471C>A p.P824Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- OR2D3 | c.512T>A p.V171E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- OR2K2 | c.923T>A p.V308E (on ENST00000374428; = p.V279E on NM_205859.2) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- OR2L2 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- OR5H1 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- OTOP2 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3 | c.3593C>T p.S1198F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH12 | c.2900C>A p.S967Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCDH18 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.079); called by muse, mutect2
- PCDHGA10 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2
- PGK2 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- PGLYRP2 | c.1233C>A p.H411Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PHB | c.394-1G>T p.X132_splice | Splice Site (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- PHLDB1 | c.1604G>A p.S535N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2
- PITPNC1 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLEKHG7 | c.195_196insAT p.W66Ifs*4 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by muse*, mutect2
- PLEKHG7 | c.197_198del p.W66Sfs*45 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by muse*, mutect2, varscan2*
- POFUT1 | c.840G>T p.M280I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- PPP1R12B | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- PPP1R16B | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF12 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PRAMEF15 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRIM1 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- PRKAR1B | c.440+1G>T p.X147_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | called by mutect2, varscan2
- PRPH | c.261C>G p.N87K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- PXDNL | c.2573C>A p.P858H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAD18 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- RAD54B | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM27 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2
- RFC3 | c.1065G>T p.M355I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- ROR2 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RTEL1 | c.1006G>C p.G336R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- RUNX1T1 | c.1574C>T p.T525I (on ENST00000265814 / NM_001198628.1; = p.T498I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.2588C>A p.T863K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2
- S100A4 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCAF4 | c.2038C>G p.P680A | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCAF8 | c.1636A>T p.I546F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SERPINE2 | c.62A>T p.H21L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFXN3 | c.950A>C p.E317A | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SKIDA1 | c.1376T>C p.V459A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- SLC22A2 | c.1131C>A p.Y377* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SLC2A3 | c.1008G>C p.M336I | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2
- SLC4A8 | c.1764C>G p.Y588* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- SLFN11 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOWAHB | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); called by mutect2, varscan2
- ST3GAL2 | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 6/79 reads (8%) | PolyPhen probably damaging (0.923); called by muse, mutect2
- SYNJ1 | c.4487C>G p.S1496* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- TARBP1 | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- TDP1 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TECTA | c.4340G>T p.R1447L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); called by muse, mutect2
- TEPSIN | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TIPRL | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- TMEM106B | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2
- TMEM135 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TMEM176B | c.413C>G p.T138R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- TMEM182 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV20 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRIP11 | c.3886G>C p.G1296R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- TRPM3 | c.299G>T p.G100V (on ENST00000357533 / NM_001366142.2; = p.G69V on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TRRAP | c.10904G>A p.R3635H (on ENST00000359863 / NM_001244580.1; = p.R3606H on NM_003496.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TSHZ2 | c.2531G>T p.R844L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TUT4 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- TYR | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGDH | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- UNC5C | c.2097C>G p.I699M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); called by muse, mutect2
- USP5 | c.2140G>T p.G714C (on ENST00000229268 / NM_001098536.2; = p.G691C on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- UVSSA | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- VPS33A | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF117 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ZNF17 | c.1862A>G p.Y621C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ZNF519 | c.933G>C p.Q311H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2
- ZNF594 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF98 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- ABCA1 | c.3222G>T p.L1074= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ACTL9 | c.399G>T p.L133= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3654C>T p.H1218= | Silent (SNP) | VAF 11/206 reads (5%) | catalogued as rs1235046090, COSV60101242, COSV60102579; called by muse, mutect2
- ADGRG3 | c.966C>A p.A322= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV59652380; called by muse, mutect2
- AFF3 | c.1167C>A p.L389= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100420330; called by muse, mutect2, varscan2
- AHNAK2 | c.3201G>T p.P1067= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- ANPEP | c.951C>A p.A317= | Silent (SNP) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- ASB2 | c.1362C>G p.G454= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ATP1A3 | c.321G>T p.L107= (on ENST00000545399 / NM_001256214.2; = p.L94= on NM_152296.5) | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- BPIFA2 | c.660C>A p.I220= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1201923012, COSV99487895; called by muse, mutect2, varscan2
- C12orf42 | c.51C>G p.T17= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CACNA1C | c.4029G>T p.G1343= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- CDH4 | c.1695G>T p.T565= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs753916349; called by muse, mutect2
- CENPA | c.234C>T p.F78= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- CENPU | c.525G>A p.E175= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CHKA | c.849C>G p.P283= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- CHST2 | c.1215G>T p.T405= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV58887013; called by muse, mutect2, varscan2
- CLCNKA | c.1473G>T p.L491= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- CLUH | c.2238G>T p.A746= (on ENST00000435359; = p.A785= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV70928636; called by muse, mutect2
- CRACDL | c.138G>T p.P46= | Silent (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- CTSG | c.225C>G p.G75= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs143803246, COSV99361379; called by muse, mutect2, varscan2
- ELAVL4 | c.594C>T p.P198= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as rs1398875262; called by muse, mutect2
- ENGASE | c.1911G>A p.E637= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- FAM47A | c.1656G>A p.R552= | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- FOXN3 | c.1209G>A p.K403= (on ENST00000261302; = p.K381= on NM_005197.4) | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FRG1 | c.729G>C p.T243= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV56996307; called by muse, mutect2
- GRIFIN | c.42C>A p.A14= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- HLA-DMA | c.576C>T p.F192= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV66386061; called by muse, mutect2
- IGHV1-46 | c.210C>A p.I70= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- INSRR | c.1947C>G p.G649= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- KLHL2 | c.165G>T p.L55= | Silent (SNP) | VAF 18/263 reads (7%) | catalogued as COSV56984073; called by muse, mutect2
- KMT2C | c.6453A>T p.T2151= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- LDB3 | c.903T>A p.P301= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- MGAM | c.519C>A p.L173= | Silent (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- MTMR14 | c.1161G>A p.E387= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- MTUS2 | c.489G>T p.L163= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- MYH2 | c.3732C>A p.V1244= | Silent (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- MYH8 | c.5286C>T p.I1762= | Silent (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- NPAS3 | c.1656G>A p.A552= (on ENST00000356141 / NM_001164749.2; = p.A520= on NM_022123.3) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1318944037; called by muse, mutect2, varscan2
- NPTXR | c.939G>T p.L313= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- NT5C1B | c.549C>G p.P183= (on ENST00000359846 / NM_001199086.2; = p.P123= on NM_033253.4) | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- OCA2 | c.171G>T p.G57= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- OR10G4 | c.846C>G p.L282= | Silent (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- OR2L3 | c.717C>A p.T239= | Silent (SNP) | VAF 32/220 reads (15%) | catalogued as COSV100741906; called by muse, varscan2
- OR4A15 | c.156C>A p.S52= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV59034850, COSV59035488; called by muse, mutect2
- OR4C15 | c.363C>T p.F121= (on ENST00000314644; = p.F67= on NM_001001920.2) | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs550631405, COSV58953178; called by muse, mutect2, varscan2
- OR4C6 | c.324G>C p.V108= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV58605580; called by mutect2, varscan2
- OR8S1 | c.375C>G p.A125= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV59600219; called by muse, mutect2, varscan2
- OXCT2 | c.732G>A p.E244= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs374640877; called by muse, mutect2, varscan2
- PCDHA1 | c.1492C>A p.R498= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV65373454; called by muse, mutect2
- PCDHA9 | c.1281G>T p.A427= | Silent (SNP) | VAF 8/195 reads (4%) | catalogued as COSV65333493; called by muse, mutect2
- PCDHB14 | c.75G>T p.R25= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV53390924; called by muse, mutect2
- PIGR | c.1011G>A p.S337= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs148222338; called by muse, mutect2, varscan2
- PKN1 | c.1867C>A p.R623= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV104387160; called by muse, mutect2
- PLPPR3 | c.354C>A p.A118= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- PMS2 | c.117A>G p.V39= | Silent (SNP) | VAF 39/504 reads (8%) | catalogued as rs34839707, COSV99764104; called by muse, mutect2
- PPP1R12A | c.2772A>G p.L924= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2, varscan2
- PRKCB | c.963G>T p.T321= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV57802987; called by muse, mutect2, varscan2
- PSMA4 | c.108A>T p.G36= | Silent (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- PTGIR | c.840C>T p.F280= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1000768786, COSV52191362; called by muse, mutect2
- RASGRP4 | c.1203C>A p.A401= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- RET | c.2656C>A p.R886= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as CM061929, COSV60699891; called by muse, mutect2, varscan2
- SIAH2 | c.552G>A p.V184= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs960477750; called by muse, mutect2
- SLC13A2 | c.951C>A p.T317= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- SLC2A6 | c.975C>A p.S325= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- SLC44A5 | c.366A>G p.P122= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- SLC6A7 | c.699C>A p.L233= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- SLITRK4 | c.450C>A p.A150= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- SLX4 | c.2709G>T p.V903= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- SPAG5 | c.1686A>T p.A562= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- SSH2 | c.486G>A p.T162= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs750724596, COSV52182222; called by muse, mutect2
- STK32B | c.597C>G p.G199= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- TET3 | c.2031G>T p.L677= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- TNNT3 | c.564G>A p.K188= (on ENST00000397301 / NM_001367846.1; = p.K177= on NM_006757.4) | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TRAV26-1 | c.174C>A p.S58= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- TRIM24 | c.1776G>C p.T592= (on ENST00000343526 / NM_015905.3; = p.T558= on NM_003852.4) | Silent (SNP) | VAF 20/231 reads (9%) | called by muse, mutect2
- TSPAN2 | c.216G>T p.V72= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- TSR2 | c.141G>T p.G47= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- TVP23A | c.612C>G p.G204= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- UVSSA | c.327G>T p.L109= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2
- WASF3 | c.1038G>T p.P346= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV58972413; called by muse, mutect2
- ZBTB22 | c.1566C>T p.F522= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56470425, COSV56471856; called by muse, mutect2, varscan2
- ZFP57 | c.753C>G p.R251= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV65307342; called by muse, mutect2, varscan2
- ZNF138 | c.342G>C p.V114= (on ENST00000307355 / NM_001367572.1; = p.V88= on NM_006524.4) | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- AL133467.6 | chr14:95668386 C>A | 5'Flank (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- BIRC8 | n.1718G>T | RNA (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- CARMIL3 | chr14:24050955 C>A | 5'Flank (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- DEPDC5 | c.*528G>T | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- DLC1 | c.1348+90586T>A | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1287G>T | RNA (SNP) | VAF 38/352 reads (11%) | catalogued as rs749992706; called by muse, mutect2, varscan2
- MIR409 | n.3G>T | RNA (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- PCDHGA10 | c.2436+68G>T | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- PRMT8 | c.418-943C>T | Intron (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- RPL7P3 | chr20:62570446 C>A | 5'Flank (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- SERPINA13P | n.370C>A | RNA (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2
- SUN5 | c.-1G>T | 5'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
